Somatic mutation profile of tumor specimen MMRF_1624_1_BM_CD138pos (aliquot MMRF_1624_1_BM_CD138pos_T1_KBS5U_L04304) from MMRF case MMRF_1624, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.8 years (25,857 days).
Specimen MMRF_1624_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62d40a50-9f4c-488e-8d10-c51f8d65007c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1624_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1624_1_PB_CD3pos_C3_KBS5U_L04315; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d5b932d-785c-4824-979a-1266ec0d74a9

The open-access MAF lists 105 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 26, Silent 12, Intron 9, 5'Flank 6, 5'UTR 5, 3'Flank 3, RNA 3, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14C | c.335C>T p.T112M (on ENST00000428251; = p.T5M on NM_152627.3) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs766356437; called by muse, mutect2, varscan2
- GRB7 | c.1014C>T p.Y338= | Splice Region (SNP) | VAF 85/135 reads (63%) | catalogued as rs769678903; called by muse, mutect2, varscan2
- GTF2IRD1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs782360413, COSV56093433; called by muse, mutect2, varscan2
- IGHV2-70 | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 78/106 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs374779982; called by muse, varscan2
- IGLV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs73880716; called by muse, mutect2, varscan2
- KL | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 95/100 reads (95%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV66310475; called by muse, mutect2, varscan2
- LCE5A | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.374); catalogued as COSV57500756; called by mutect2, varscan2
- MUC16 | c.1813G>T p.V605F | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs540756541, COSV67461210; called by muse, mutect2, varscan2
- OR5D13 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62334171; called by muse, mutect2, varscan2
- PCDHA10 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1554150713, COSV56534395; called by muse, mutect2, varscan2
- STAB2 | c.3355G>T p.V1119L | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV66337882; called by muse, mutect2, varscan2
- TCF4 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs769123898; called by muse, mutect2, varscan2
- UBE3A | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV51669162; called by muse, mutect2, varscan2
- WDR7 | c.4369C>T p.P1457S | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as COSV99590016; called by muse, mutect2
- ADCK2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 74/83 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADM | c.220_223del p.K74Vfs*25 | Frame Shift Del (DEL) | VAF 102/177 reads (58%) | called by mutect2, varscan2
- ANK2 | c.7851A>T p.Q2617H | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CDH8 | c.1863G>A p.M621I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH9 | c.2094T>G p.F698L | Missense Mutation (SNP) | VAF 88/295 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CEP89 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CEP89 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- CKAP5 | c.4834A>G p.K1612E | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- COL6A5 | c.7337G>T p.G2446V (on ENST00000312481; = p.G2442V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST9 | c.467A>C p.D156A | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX60L | c.3176A>G p.E1059G | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM117B | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- H2AC4 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITPR3 | c.2981T>C p.F994S | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- KRT33B | c.902C>G p.T301R | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- KSR2 | c.2256G>C p.R752S | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.6181A>G p.T2061A | Missense Mutation (SNP) | VAF 267/357 reads (75%) | SIFT tolerated, low confidence (0.21); called by muse, mutect2, varscan2
- NXPH3 | c.4C>G p.Q2E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASGRF2 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STRA8 | c.81A>C p.E27D (on ENST00000275764; = p.E5D on NM_182489.2) | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TACC2 | c.4854T>A p.F1618L | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBP | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
- TFR2 | c.1594G>T p.V532F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- THOC2 | c.2173T>C p.S725P | Missense Mutation (SNP) | VAF 92/93 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZNF468 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 63/513 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF682 | c.1457G>T p.C486F | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF875 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- C10orf90 | c.1641C>T p.R547= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs370692288; called by muse, varscan2
- DHTKD1 | c.2193T>A p.T731= | Silent (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- EMC1 | c.2400T>C p.A800= | Silent (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- HELB | c.2004C>T p.I668= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- HOXD3 | c.849C>T p.S283= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1174687820, COSV50880669; called by muse, mutect2, varscan2
- NEXMIF | c.303C>A p.L101= | Silent (SNP) | VAF 39/39 reads (100%) | catalogued as COSV99279257; called by muse, mutect2, varscan2
- RSPH6A | c.1047G>T p.L349= | Silent (SNP) | VAF 133/440 reads (30%) | called by muse, mutect2, varscan2
- SPO11 | c.1126C>T p.L376= | Silent (SNP) | VAF 105/108 reads (97%) | catalogued as COSV100625587; called by muse, mutect2, varscan2
- TNXB | c.5403G>A p.L1801= (on ENST00000647633; = p.L1554= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/241 reads (27%) | called by muse, mutect2, varscan2
- TRMT2A | c.1725G>A p.P575= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs146551748; called by muse, mutect2, varscan2
- TRRAP | c.549A>G p.T183= | Silent (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- XYLT1 | c.2178G>A p.K726= | Silent (SNP) | VAF 39/76 reads (51%) | called by muse, varscan2
- ADAM32 | c.*6C>T | 3'UTR (SNP) | VAF 175/344 reads (51%) | called by muse, mutect2, varscan2
- AP1B1 | c.*820G>A | 3'UTR (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- APCDD1L | c.-81G>A | 5'UTR (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- ARRB1 | c.*1474C>A | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- ATR | c.7761+1513A>T | Intron (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- BAGE2 | n.699G>T | RNA (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- C12orf4 | c.*1695A>G | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- CD93 | c.*993G>C | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- CEP41 | c.*1984C>T | 3'UTR (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- CEP89 | c.1029+81C>A | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99993185; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33720G>A | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as rs200719061; called by muse, mutect2, varscan2
- CNP | c.*1036C>T | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- COL18A1 | c.3624+32G>T | Intron (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- DEFB132 | c.*361C>T | 3'UTR (SNP) | VAF 5/54 reads (9%) | catalogued as rs1331068793; called by muse, mutect2
- DENND4C | chr9:19372868 A>G | 3'Flank (SNP) | VAF 16/26 reads (62%) | called by muse, varscan2
- DENND4C | chr9:19373041 A>T | 3'Flank (SNP) | VAF 30/47 reads (64%) | called by muse, mutect2, varscan2
- ELF2 | c.239-10802C>T | Intron (SNP) | VAF 88/182 reads (48%) | catalogued as rs1165369768; called by muse, mutect2, varscan2
- ENPEP | c.*1968T>A | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- EXOC5 | c.*2811T>G | 3'UTR (SNP) | VAF 62/192 reads (32%) | catalogued as COSV61770085; called by muse, mutect2, varscan2
- FAM43A | c.*231A>C | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- GASK1A | c.*146+957G>A | Intron (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- GRAMD1B | c.24-16867G>A | Intron (SNP) | VAF 26/77 reads (34%) | called by muse, varscan2
- HOATZ | c.452+224G>T | Intron (SNP) | VAF 12/397 reads (3%) | called by muse, mutect2
- HSPA12A | c.*1616C>T | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- KLHL1 | c.*1080A>G | 3'UTR (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- MMACHC | c.*1026G>T | 3'UTR (SNP) | VAF 9/51 reads (18%) | catalogued as COSV53114102; called by muse, mutect2, varscan2
- MROH1 | c.*23G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs1554836109; called by muse, mutect2, varscan2
- MTR | c.-159C>G | 5'UTR (SNP) | VAF 82/119 reads (69%) | called by muse, mutect2, varscan2
- OLFML2A | c.*4051dup | 3'UTR (INS) | VAF 31/156 reads (20%) | catalogued as rs5900626; called by mutect2, varscan2
- PKD1L2 | n.929G>A | RNA (SNP) | VAF 18/46 reads (39%) | catalogued as rs772471006; called by muse, mutect2, varscan2
- PPP3R1 | c.*903A>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- RAMP3 | c.*53C>T | 3'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99642233; called by muse, mutect2, varscan2
- RRP8 | c.*2241T>C | 3'UTR (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- SAT1 | c.-154T>G | 5'UTR (SNP) | VAF 42/42 reads (100%) | catalogued as rs1206761977; called by muse, mutect2, varscan2
- SERTAD4 | c.*159C>T | 3'UTR (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- SFTA3 | n.1124A>T | RNA (SNP) | VAF 85/245 reads (35%) | called by muse, mutect2, varscan2
- SLC35F3 | c.-189G>T | 5'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs1264476982; called by muse, mutect2
- SLITRK4 | chrX:143627934 T>A | 3'Flank (SNP) | VAF 74/75 reads (99%) | called by muse, mutect2, varscan2
- SSU72 | chr1:1575350 T>C | 5'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- SYNPO | c.*2612G>C | 3'UTR (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- TLR2 | c.-1138dup | 5'UTR (INS) | VAF 55/149 reads (37%) | catalogued as rs1189493725; called by pindel, varscan2
- TM9SF3 | c.*3464T>C | 3'UTR (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975351 A>T | 5'Flank (SNP) | VAF 74/74 reads (100%) | called by muse, varscan2
- TMSB4X | chrX:12975364 A>G | 5'Flank (SNP) | VAF 66/66 reads (100%) | called by muse, varscan2
- TMSB4X | chrX:12975446 A>G | 5'Flank (SNP) | VAF 78/78 reads (100%) | called by muse, varscan2
- TMSB4X | chrX:12975592 A>G | 5'Flank (SNP) | VAF 88/88 reads (100%) | called by muse, varscan2
- TOR2A | c.594-83G>A | Intron (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- TSLP | chr5:111070494 G>A | 5'Flank (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- UBXN10 | c.*4269C>A | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- ZNF493 | c.*154C>G | 3'UTR (SNP) | VAF 58/620 reads (9%) | catalogued as rs1192529132, COSV62749196; called by muse, mutect2
- ZNF780B | c.*4830C>T | 3'UTR (SNP) | VAF 16/464 reads (3%) | called by muse, mutect2
- ZNF844 | c.*2562G>T | 3'UTR (SNP) | VAF 53/90 reads (59%) | called by muse, mutect2, varscan2
